Surgical pathology report (de-identified scan), TCGA case TCGA-FP-A8CX, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FP-A8CX-01A (Primary Tumor).

[page 1 of 6]
Referring Physician:

DOB: Age Gender: M

Ref#: Hosp#: Provider Group:

Date of Service: Date Received:

Case #

Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

ICD O.3

Diagnosis:

A. GALLBLADDER, CHOLECYSTECTOMY:

- MINIMAL CHRONIC CHOLECYSTITIS.
- NEGATIVE FOR DYSPLASIA.

cell
Adenocarcinoma, signet ring
cell 849013
Carcinoma, signet ring cell 84901E
Site: Body of stomach C16.2
Lesser curvature of stomach C16.2
7/24/17/14

B. - C. GASTROJEJUNOSTOMY AND GASTROESOPHAGEAL SPECIMEN, TOTAL GASTRECTOMY WITH RESECTION OF GASTROJEJUNOSTOMY:

- INVASIVE SIGNET RING CELL CARCINOMA, FORMING A 13.8 CM ULCERATING MASS WITHIN THE LESSER CURVATURE OF THE STOMACH WITH DIRECT EXTENSION THROUGH MUSCULARIS PROPRIA OF SMALL BOWEL INTO JEJUNAL MUCOSA (AREA OF GASTROJEJUNOSTOMY).
- TUMOR ALSO INVADIES THROUGH MUSCULARIS PROPRIA OF STOMACH INTO PERIGASTRIC ADIPOSE TISSUE (WITHIN 0.1 CM OF SEROSA).
- MARGINS ARE NEGATIVE:
- TUMOR IS 0.4 CM FROM CLOSEST PERIGASTRIC RADIAL MARGIN AND AT LEAST 1.2 CM AWAY FROM REMAINING MARGINS (RADIAL MARGIN OF SMALL BOWEL, PROXIMAL AND DISTAL SMALL BOWEL MARGINS, AND PROXIMAL ESOPHAGEAL MARGIN).
- LYMPHOVASCULAR INVASION AND PERINEURAL INVASION IDENTIFIED.
- METASTATIC CARCINOMA IDENTIFIED IN FIFTEEN OF TWENTY-FIVE REGIONAL LYMPH NODES (15/25) (SEE COMMENT).
- LARGEST TUMOR METASTASIS MEASURES AT LEAST 0.4 CM.
- NO EXTRANODAL EXTENSION IDENTIFIED.
- UNINVOLVED STOMACH WITH CHRONIC ACTIVE GASTRITIS AND FOCAL INTESTINAL METAPLASIA.
- NEGATIVE FOR HELICOBACTER ORGANISMS BY IMMUNOSTAIN.
- GASTROESOPHAGEAL JUNCTION WITH CHRONIC AND ACUTE INFLAMMATION WITH FOCAL INTESTINAL METAPLASIA, NEGATIVE FOR DYSPLASIA.

COMMENT: Two regional lymph nodes showed macrometastasis, while thirteen additional lymph nodes showed occult metastasis in the form of isolated tumor cells,

Case #

Page 1

Printed:

This report continues... (FINAL)

[page 2 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

which are better appreciated with OSCAR-cytokeratin immunostains. Controls are appropriate.

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade (invasive): Signet ring cell carcinoma, poorly differentiated.

Primary tumor: pT4b.

Regional lymph nodes: pN3a.

Distant metastasis: N/A.

Stage: IIIC.

Lymphovascular invasion: Present.

Margin status: R0, negative.

Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol.

Case #

Printed:

Page 2

This report continues. (FINAL)

[page 3 of 6]
Patient:

Case #

Procedure:	Total gastrectomy with resection of gastrojejunostomy.
Specimen:	Gastrojejunostomy and distal esophagus.
Tumor site:	Body (lesser curvature) and jejunum (gastrojejunostomy).
Tumor size (greatest dimension):	13.8 cm.
Histologic type:	Signet ring cell carcinoma.
Histologic grade:	Poorly differentiated.
Extent of tumor:	Tumor directly invades adjacent jejunum (area of gastrojejunostomy).
MARGINS:	
Distance of carcinoma from closest margin:	0.4 cm (gastric radial margin).
Proximal margin (includes gastroesophageal specimen):	Uninvolved by invasive carcinoma (~10 cm away).
Small bowel proximal and distal margins:	Uninvolved by invasive carcinoma (at least 3.7 cm away)
Small bowel radial margin:	Uninvolved by invasive carcinoma (1.2 cm away).
Treatment effect:	No prior treatment.
Lymph-vascular invasion:	Present
Perineural invasion:	Present.
PATHOLOGIC TUMOR STAGING:	
Primary tumor:	pT4b.
Regional lymph nodes:	pN3a
Number of lymph nodes examined:	25.
Number of nodes involved:	15.
Distant metastasis:	N/A.
Stage:	IIIC.
Additional pathologic findings:	Intestinal metaplasia and chronic active gastritis; H pylori immunostain is negative.

Case #

Printed:

Page 3

This report continues. (FINAL)

MR No.
Pathology - Page 3/6

Acct No.

Patient Name -

Doc# 1

[page 4 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Gallbladder
- B. Gastrojejunostomy
- C. Gastroesophageal

Intraoperative Diagnosis:

- B. Gastrojejunostomy, gross evaluation/intraoperative consultation: Tumor less than 5 mm of proximal gastric margin, grossly (reviewed with [REDACTED])
- C. Gastroesophageal specimen, FS: Proximal esophageal margin negative for tumor. [REDACTED]

The intraoperative interpretation(s) was/were performed and rendered at [REDACTED]

Gross Description:

A. Part A designated gallbladder. Received in formalin is an intact gallbladder 8.3 x 3.3 x 2.8 cm. The serosa is partially glistening, hyperemic pink and tan with scant fibrofatty adhesions. The cystic duct margin demonstrates a patent 0.3 cm lumen. The wall is 0.1 - 0.2 cm and the lumen contains copious amount of viscous dark green bile without calculi; no calculi present within the container. The mucosa is tan, velvety, dark green without grossly unusual areas of change suggestive of neoplasia. Representative sections are submitted in A1. [REDACTED]

B. Part B is gastrojejunostomy. Initially received in the fresh state for frozen section/intraoperative consultation of a gastrojejunostomy revision specimen. The portion of stomach is 14.5 cm along the lesser curvature with the adjacent margin of resection closed by a 14.1 cm line of surgical staples. The attached anastomosing limbs of the jejunum are 5.0 x 3.1 cm and 5.7 x 2.9 cm each. The radial surface of the gastric resection with adherent fat is marked green, with the margin of the possible mesenteric jejunum is marked black.

The gastrojejunostomy is opened to reveal an ulcerated mass lesion measuring up to 13.8 x 4.7 cm that, initially, grossly approaches within 0.5 cm of the likely superior-proximal margin of resection, anteriorly, and greater than 2.0 cm to the nearest posterior, proximal gastric margin of resection. The mass appears to be centered at the gastro-jejunal outlet, partially obliterating the involved small bowel mucosa. The tumor grossly approaches 3.7 cm of the nearest small bowel margin of resection (shortest branch, B2). Sectioning through the tumor oriented nearest to the anterior-superior, most proximal surgical margin, reveals full thickness muscular involvement, to within 0.2 cm of the margin of resection (orange) and 0.1 cm of the serosa.

The tumor reveals full thickness involvement through the small bowel muscularis and into the mesenteric fat, within 1.2 cm of the radial surgical margin (B10). Cut sections of the gastric tumor relationship with the perigastric fat/radial surgical margins is difficult to obtain attributed to the presence of numerous

Case #

Printed:

Page 4

This report continues.. (FINAL)

[page 5 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

embedded surgical staples from the historic gastrojejunostomy. The tumor appears to approach within 0.4 cm of the nearest perigastric fat radial surgical margin (B11). The uninvolved gastric mucosa is predominantly flattened, tan to dusky red without additional ulcerations/lesions. The opposing ends of the small bowel limbs demonstrates prominent semi-congested, pink and tan-red circular plica without additional lesion.

Examination of the scant amount of perigastric/mesenteric fat reveals six lymph nodes ranging from 0.3 - 0.5 cm. Lymph nodes entirely submitted.

Cassette summary:

B1-B2) long and short small bowel branches, margins of resection, respectively.
B3-B6) perpendicular demonstration of tumor mass advancing to gastric margin of resection, and abutting radial surface.
B7-B9) remainder of gastric margin of resection, trimmed and submitted en face.
B10) small bowel mesenteric radial margin.
B11-B14) representation of gastric tumor including radial surgical margin.
B15) tumor at outlet, including relationship with adjacent longer limb of small bowel.
B16) tumor at outlet, including relationship with adjacent shorter limb of small bowel.
B17) longer and short limbs of small bowel, uninvolved near margins of resection, one piece each.
B18) three lymph nodes.
B19) three lymph nodes.

C. Part C designated gastroesophageal. Initially received in a fresh state for frozen section evaluation, is a portion of tissue, consisting of a 1.2 cm length of esophagus, 1.9 cm in diameter, attached to a wedge-like resection of gastric tissue 9.3 cm along the curvature and 3.8 cm in diameter at the distal end. A moderate amount of perigastric-esophageal fat is attached circumferentially at the esophagus and apparent cardia. This surface is now marked green.

The proximal esophageal margin is now trimmed and submitted for frozen section evaluation with the residual frozen tissue submitted in C1 for permanent sections. The remainder length of the esophagus is opened and the stomach is opened along the line of surgical staples to reveal prominent edematous pink and tan rugae, without discrete ulceration, polypoid changes or induration of the gastric wall. The submucosa is edematous. The Z-line is oriented at the gastroesophageal junction, well demarcated, with the esophageal component glistening, lighter tan. No lesions are appreciated.

Examination of the perigastric-esophageal fat, reveals twenty-three lymph nodes ranging from 0.2 - 1.0 x 0.7 cm. The lymph nodes are entirely submitted for microscopic evaluation along with representation of gastroesophageal tissue.

Cassette summary:

C1) frozen section, proximal esophageal surgical margin.
C2-C4) esophageal junction/Z-line, full thickness, including radial margin.
C5-C6) representation of stomach.
C7) six small lymph nodes.

Case #

Printed:

Page 5

This report continues. (FINAL)

MR No
Pathology - Page 5/6

Acct Nc

Patient Name

[page 6 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

C8) six lymph nodes,
C9) six lymph nodes,
C10) four lymph nodes,
C11) largest lymph node, bisected

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. - C Sections show a poorly differentiated adenocarcinoma with extensive signet ring cell features (>50%), consistent with signet ring cell carcinoma. The tumor is ulcerating and extensively involves the lesser curvature of the stomach, extending through the gastric wall and directly invading through adjacent small bowel muscularis propria to involve the mucosal surface of the small bowel (area of gastrojejunostomy). Tumor extends to 0.2 cm of the proximal resection margin of the initial gastric specimen (not final margin). However, the additional gastroesophageal specimen is negative for tumor. Thus, the final proximal resection margin is negative for tumor. OSCAR-cytokeratin immunostain performed on all blocks of lymph nodes (B18, B19, C7, C8, C9, C10, and C11) highlight thirteen nodes with occult isolated tumor cells as well as two obvious metastases. The gastroesophageal specimen shows chronic focal active inflammation with intestinal metaplasia. The gastric mucosa also shows chronic active gastritis. An immunostain for Helicobacter is negative. Controls are appropriate. See synoptic report for summary.

Case #:

Printed:

Page 6

END OF REPORT (FINAL)

MR No.
Pathology - Page 6/6

Acct Nr

Patient Name

. 6 Doc# 1

Criteria	11/3/13	Yes	No
HPA Discrepancy	(no +)		

Source: NCI Genomic Data Commons file ad82441e-b8d9-488e-8723-d8d29816c5b4 (TCGA-FP-A8CX.630E6B6D-FA2E-4E64-870E-F8C6DDA53B14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).